Somatic mutation profile of tumor specimen 0DS4MD from CCDI case PBCHFL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.2 years (5,920 days).
Specimen 0DS4MD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d72b9d0-f1cf-4a8c-a684-d8fac83ca733.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS4MJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33eab4f8-8a0b-4edc-9840-b139b18af791

The open-access MAF lists 45 somatic variants for this specimen: 28 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, 3'UTR 3, Frame Shift Del 2, Splice Site 2, Intron 2, RNA 1, 5'UTR 1, Splice Region 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.3482G>A p.R1161H | Missense Mutation (SNP) | VAF 278/540 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs768278935, CM1312845, CM161697; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 171/304 reads (56%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, mutect2, varscan2
- PDGFRA | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 200/392 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57265219, COSV57268286, COSV57271923; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 202/470 reads (43%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DHX15 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 132/303 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.041); catalogued as rs1333526601, COSV100391446; called by muse, mutect2, varscan2
- FRAS1 | c.8342G>A p.R2781H | Missense Mutation (SNP) | VAF 152/160 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs373377563; called by muse, mutect2, varscan2
- GAS2L3 | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 173/390 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV57156626; called by muse, mutect2, varscan2
- HAUS5 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 130/270 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.742); catalogued as rs376044773; called by muse, mutect2, varscan2
- HSPG2 | c.2678G>A p.R893H | Missense Mutation (SNP) | VAF 105/273 reads (38%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.515); catalogued as rs751663070, COSV65978320; called by muse, mutect2, varscan2
- MUC16 | c.9800C>G p.T3267R | Missense Mutation (SNP) | VAF 23/560 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV67502809; called by muse, mutect2
- OR2F2 | c.902G>C p.W301S | Missense Mutation (SNP) | VAF 122/295 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV68832693; called by muse, mutect2, varscan2
- PCDH9 | c.3036+6C>T | Splice Region (SNP) | VAF 151/169 reads (89%) | catalogued as rs201178169; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1060+1G>A p.X354_splice | Splice Site (SNP) | VAF 161/391 reads (41%) | catalogued as rs753678221; called by muse, mutect2, varscan2
- SCN2B | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 230/533 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs774866184; called by muse, mutect2, varscan2
- TMEM132D | c.2557C>T p.R853W | Missense Mutation (SNP) | VAF 170/372 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1010391944, COSV67161510; called by muse, mutect2, varscan2
- ZMYM4 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 180/436 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs745941371; called by muse, mutect2, varscan2
- ATRX | c.3809+1G>T p.X1270_splice | Splice Site (SNP) | VAF 114/123 reads (93%) | called by mutect2, varscan2
- COASY | c.1548G>C p.Q516H | Missense Mutation (SNP) | VAF 206/453 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- COL26A1 | c.95T>A p.L32Q | Missense Mutation (SNP) | VAF 174/386 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- DOCK1 | c.3731C>T p.A1244V | Missense Mutation (SNP) | VAF 146/347 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- GLCCI1 | c.750C>A p.H250Q | Missense Mutation (SNP) | VAF 111/251 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ITGA5 | c.2413T>C p.F805L | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- KBTBD13 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 109/246 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- KIF24 | c.1061_1062del p.F354Cfs*7 | Frame Shift Del (DEL) | VAF 178/434 reads (41%) | called by mutect2, varscan2
- PLOD2 | c.1703T>G p.F568C | Missense Mutation (SNP) | VAF 189/452 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASD1 | c.400_402del p.E134del | In Frame Del (DEL) | VAF 180/394 reads (46%) | called by mutect2, varscan2
- SLF2 | c.1715C>A p.P572H | Missense Mutation (SNP) | VAF 205/474 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZNF22 | c.362_365del p.K121Rfs*61 | Frame Shift Del (DEL) | VAF 134/261 reads (51%) | called by mutect2, varscan2
- AMER3 | c.835C>T p.L279= | Silent (SNP) | VAF 98/225 reads (44%) | called by muse, mutect2, varscan2
- C2orf68 | c.500G>A p.*167= | Silent (SNP) | VAF 72/126 reads (57%) | called by mutect2, varscan2
- CRMP1 | c.900G>A p.A300= | Silent (SNP) | VAF 205/437 reads (47%) | catalogued as rs927839954; called by muse, mutect2, varscan2
- GLP2R | c.972C>T p.H324= | Silent (SNP) | VAF 130/259 reads (50%) | called by muse, mutect2, varscan2
- L3MBTL2 | c.1827G>A p.P609= | Silent (SNP) | VAF 238/571 reads (42%) | catalogued as rs35655247; called by muse, mutect2, varscan2
- LTK | c.2286C>T p.H762= | Silent (SNP) | VAF 99/216 reads (46%) | catalogued as rs556097894, COSV53026374; called by muse, mutect2, varscan2
- NOVA2 | c.894G>A p.L298= | Silent (SNP) | VAF 106/242 reads (44%) | called by muse, mutect2
- OR4P4 | c.306C>A p.T102= | Silent (SNP) | VAF 112/222 reads (50%) | called by muse, mutect2, varscan2
- SRFBP1 | c.1263G>A p.Q421= | Silent (SNP) | VAF 13/278 reads (5%) | catalogued as rs1166519026; called by muse, mutect2
- TAS1R2 | c.432C>T p.S144= | Silent (SNP) | VAF 167/344 reads (49%) | catalogued as rs778530316, COSV100946374; called by muse, mutect2, varscan2
- ART4 | c.*33del | 3'UTR (DEL) | VAF 87/161 reads (54%) | catalogued as rs749797269; called by mutect2, varscan2
- COL25A1-DT | n.1305G>A | RNA (SNP) | VAF 178/193 reads (92%) | called by muse, mutect2, varscan2
- KMO | c.*2197T>A | 3'UTR (SNP) | VAF 21/78 reads (27%) | called by mutect2, varscan2
- MTSS1 | c.*86_*90del | 3'UTR (DEL) | VAF 28/56 reads (50%) | catalogued as rs1249669978; called by mutect2, varscan2
- OR2J3 | c.-18del | 5'UTR (DEL) | VAF 47/89 reads (53%) | called by mutect2, varscan2
- PTPRQ | c.5913-77C>A | Intron (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- ZNF211 | c.90+584C>T | Intron (SNP) | VAF 59/135 reads (44%) | called by muse, mutect2, varscan2
